TCGA case TCGA-BF-A1PU — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: Cureline. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3dd5a206-d7f3-42f1-b9cc-4b31c76d495d

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Russia; Age at index: 46 years; Vital status: Alive.

Diagnoses (5)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 46.6 years (17,025 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 484 days (1.3 years); Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Extremities; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: >4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 47.9 years (17,509 days); Days to diagnosis: 484 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 484 days (1.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Bone, NOS. Age at diagnosis: 47.9 years (17,509 days); Days to diagnosis: 484 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 484 days (1.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 47.9 years (17,509 days); Days to diagnosis: 484 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 484 days (1.3 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Days to follow up: 387 days (1.1 years); Disease response: Tumor Free.
- Day 484 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 484 days (1.3 years).
- Day 484 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 484 days (1.3 years).
- Day 484 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 484 days (1.3 years).

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 160 cm; BMI: 22.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BF-A1PU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-BF-A1PU-01A-01-TSA: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 95; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BF-A1PU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BF-A1PU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 13; Radiation therapy to primary: No; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No; Primary at diagnosis count: 1.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 387 days; disease-specific survival: no event (censored), 387 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 484 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BF-A1PU-01A-11D-A192-01): tumor purity 0.92, ploidy 1.76, whole-genome doublings 0.
